CCDI case PBCLAF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d5e71957-b80f-40b7-9fe0-3839b8889720

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Choroid plexus carcinoma: ICD-O-3 morphology code: 9390/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.2 years (65 days).

Biospecimens (3 samples)
- Sample 0DUCRK: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUCRQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUCU1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
